Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A2JK, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A2JK-06A (Metastatic).

1CB-0-3
Melanoma, NOS 8720/3
Site: lymph node, axillary 277.3
lw 7/24/11

DIAGNOSIS

Patient ID – Sample ID

(A) LEFT AXILLARY CONTENTS, BIOPSY:

**METASTATIC MELANOMA IN FIBROADIPOSE TISSUE AND THREE OF ELEVEN (3/11) LYMPH NODES
LARGEST DEPOSIT IS 60 X 50 X 30 MM IN SOFT TISSUE; AN ENTIRELY REPLACED LYMPH NODE NOT RULED
OUT.**

(B) HIGHEST AXILLARY LYMPH NODES, BIOPSY:

Two lymph nodes, metastatic melanoma not identified (0/2).

(C) LEFT FLANK, SKIN, WIDE LOCAL EXCISION:

Skin and soft tissue resection with healing surgical wound. See note.

Note: There is no malignant melanoma identified in these sections. Margins have been evaluated.

Entire report and diagnosis completed by

GROSS DESCRIPTION

(A) LEFT AXILLARY CONTENTS - An axillary fat pad, 11.2 x 10.9 x 3.9 cm.

A large firm lymph node involved by black-tan tumor, 6.0 x 5.0 x 3.0 cm. Multiple small firm lymph nodes, 0.5-1.5 cm.

Representative sections from the largest lymph node were submitted for tumor bank.

SECTION CODE: A1-A7, largest lymph nodes, representative sections; A8, two lymph nodes; A9, one trisected lymph node; A10, one lymph node; A11, one bisected lymph node; A12, one bisected lymph node; A13, one bisected lymph node; A14, one bisected lymph node; A15, one bisected lymph node; A16, one bisected lymph node.

(B) HIGHEST AXILLARY NODES - Two firm lymph nodes, 0.3 and 0.6 cm.

SECTION CODE: B1, two lymph nodes.

(C) 2 CM WIDE LOCAL EXCISION MELANOMA LEFT FLANK - A tan-white oriented ellipse of skin (10.0 x 4.0 x 2.0 cm). The specimen is oriented as short stitch superior side, long stitch lateral tips. On the surface of the specimen a healed scar (4.0 cm in length). The specimen is serially sectioned from lateral to medial tip.

INK CODE: Superior - blue, inferior - yellow.

SECTION CODE: C1, lateral tip - stitch marks; C2, medial tip; C3-C10, entire scar submitted from lateral to medial; C11, superior side - blue - shaved - inked side down; C12, inferior side - yellow - shaved - inked side down; C13, deep margin - shaved - inked side down.

CLINICAL HISTORY

Melanoma.

SNOMED CODES

"Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

These tests have not been

Released by:

Source: NCI Genomic Data Commons file 22e26092-6add-40a1-92c2-e46f97bd7238 (TCGA-D3-A2JK.72B16AA4-3708-485B-8DC2-20BCD5BDF9DE.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).